Somatic mutation profile of tumor specimen 3dcf8b3c-c0c5-4dfa-9543-5d30fb (aliquot 3dcf8b3c-c0c5-4dfa-9543-5d30fb_D6) from CPTAC case 04OV044, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 3dcf8b3c-c0c5-4dfa-9543-5d30fb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 531eebea-5542-41ce-808e-de4937a2cdbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ea3b2f6d-f072-4830-b5e8-80a57a (Blood Derived Normal), aliquot ea3b2f6d-f072-4830-b5e8-80a57a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bba486d-a9b5-4c9d-96cc-7d39cd01d705

The open-access MAF lists 200 somatic variants for this specimen: 133 protein-altering or splice-affecting, 28 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 28, Intron 17, Nonsense Mutation 7, RNA 6, 3'UTR 6, 5'Flank 5, 3'Flank 3, In Frame Del 2, Splice Region 2, Frame Shift Del 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3847_3849del p.F1283del | In Frame Del (DEL) | VAF 39/150 reads (26%) | catalogued as rs1044692541; called by pindel, varscan2
- ADAD2 | c.1213G>A p.V405M (on ENST00000315906 / NM_001145400.2; = p.V487M on NM_139174.4) | Missense Mutation (SNP) | VAF 123/426 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs749960477; called by muse, mutect2, varscan2
- ADGRV1 | c.12460G>A p.A4154T | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV67992172; called by muse, mutect2, varscan2
- ATF6B | c.1015G>C p.A339P | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201247380; called by muse, mutect2, varscan2
- CCDC73 | c.1803C>G p.F601L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58800468, COSV58805890; called by muse, mutect2
- CHSY3 | c.2539T>A p.Y847N | Missense Mutation (SNP) | VAF 106/177 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100519442; called by muse, mutect2, varscan2
- DYRK1A | c.2080C>A p.Q694K | Missense Mutation (SNP) | VAF 110/578 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100117852; called by muse, mutect2, varscan2
- FEV | c.327C>A p.Y109* | Nonsense Mutation (SNP) | VAF 40/245 reads (16%) | catalogued as COSV55387386; called by muse, varscan2
- ICAM1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 52/684 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99320897; called by muse, mutect2
- IGKV1-8 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 109/441 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369059950; called by muse, mutect2, varscan2
- KRBA1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55443016; called by muse, mutect2, varscan2
- KRT15 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs778649261; called by muse, mutect2, varscan2
- LRP1B | c.2062A>C p.I688L | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV67186843; called by muse, mutect2, varscan2
- MAP2K4 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62259076; called by muse, mutect2, varscan2
- MEP1B | c.1770C>A p.H590Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99329251; called by muse, mutect2, varscan2
- NASP | c.2339G>C p.G780A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs374820739; called by muse, mutect2, varscan2
- NDST4 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 105/211 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs761881744; called by muse, mutect2, varscan2
- OR4D10 | c.302T>A p.M101K | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1033191404; called by muse, mutect2, varscan2
- OR5M3 | c.344C>A p.A115E | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV56567428; called by muse, mutect2, varscan2
- PCDH11X | c.2912C>T p.T971I | Missense Mutation (SNP) | VAF 122/708 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350438621; called by mutect2, varscan2
- RIMS1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1044390019, COSV53488608; called by muse, mutect2, varscan2
- RXYLT1 | c.491T>A p.L164H | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1440497370; called by muse, mutect2, varscan2
- SAMD9 | c.3181G>C p.D1061H | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs751226142; called by muse, mutect2, varscan2
- SCAF8 | c.3061A>G p.I1021V | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs568823608; called by muse, mutect2, varscan2
- SCAMP2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1390794039; called by muse, mutect2
- SCUBE3 | c.2776G>T p.D926Y | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1004141806; called by muse, mutect2, varscan2
- SGMS1 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 19/541 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs943099518; called by muse, mutect2
- SLC24A1 | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 15/230 reads (7%) | catalogued as rs763074752; called by muse, mutect2
- SLC25A43 | c.502T>G p.S168A | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.338); catalogued as COSV99474872; called by muse, mutect2, varscan2
- SLC4A5 | c.3399G>C p.W1133C | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61030659; called by muse, mutect2, varscan2
- SMAP2 | c.572-1G>C p.X191_splice | Splice Site (SNP) | VAF 42/152 reads (28%) | catalogued as COSV101019356; called by muse, mutect2, varscan2
- SSX2IP | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 34/58 reads (59%) | catalogued as COSV100642517; called by muse, mutect2, varscan2
- SYNE2 | c.11849A>C p.Y3950S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs750051898; called by muse, mutect2, varscan2
- TCERG1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57042264; called by muse, mutect2, varscan2
- TRMT11 | c.590C>G p.T197R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374480497; called by muse, mutect2, varscan2
- TXNDC12 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs764676139; called by muse, mutect2, varscan2
- VNN3 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs540192101, COSV51592657; called by muse, mutect2, varscan2
- WNT10A | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1188846817; called by muse, mutect2
- XCL1 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV63192414; called by muse, mutect2, varscan2
- YEATS2 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.98); catalogued as rs751502638; called by muse, mutect2, varscan2
- ZNF485 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1487305763; called by muse, mutect2, varscan2
- ADAP2 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ADGRG7 | c.1377C>T p.T459= | Splice Region (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- ALMS1 | c.2691G>C p.K897N | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ALPK3 | c.1637A>C p.H546P | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO2 | c.902C>T p.A301V (on ENST00000356134 / NM_001278597.3; = p.A305V on NM_001278596.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANO5 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ANXA5 | c.189G>C p.R63S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ATP8B1 | c.3022A>T p.S1008C | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ATRNL1 | c.2354C>G p.S785* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- BEND3 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 63/509 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BOC | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRD4 | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CCNB3 | c.791del p.E264Gfs*3 | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | called by mutect2, varscan2
- CEP152 | c.1288A>T p.S430C | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- CIT | c.3745G>T p.A1249S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP27B1 | c.1211A>C p.K404T | Missense Mutation (SNP) | VAF 174/462 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CYP8B1 | c.1440G>C p.W480C | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- DNAH5 | c.7623C>G p.H2541Q | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- DNMT1 | c.3157T>C p.F1053L | Missense Mutation (SNP) | VAF 72/825 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2
- EPAS1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 9/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ETFDH | c.1567G>C p.A523P | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- F2 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARS2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FBN3 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- GABRA2 | c.111T>G p.N37K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GARS1 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- GOLM1 | c.1120A>C p.N374H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- GPD1 | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDX | c.1768A>G p.S590G | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HEMGN | c.50A>T p.D17V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HES3 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- HNRNPD | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- IGSF10 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCB1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 68/713 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- IRGQ | c.1643C>G p.P548R | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, varscan2
- LAMA2 | c.6965A>T p.E2322V | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LAMA4 | c.1501G>C p.D501H (on ENST00000230538 / NM_001105206.3; = p.D494H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/650 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2
- LRP3 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 46/1327 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2
- LRRC2 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAP6 | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- MCMDC2 | c.228C>G p.V76= | Splice Region (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- MGAT2 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); called by muse, varscan2
- MGAT2 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, varscan2
- MMEL1 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.071); called by muse, varscan2
- MROH1 | c.1884C>A p.S628R | Missense Mutation (SNP) | VAF 209/702 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- MRPL13 | c.251C>G p.P84R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MRRF | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC5B | c.2147G>C p.S716T | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MVD | c.348C>G p.N116K | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCKAP5 | c.5243C>T p.A1748V | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEDD4 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2
- NUP205 | c.1823T>G p.I608S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- OR13G1 | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 91/484 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR4D5 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 143/567 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4X2 | c.533A>T p.K178I | Missense Mutation (SNP) | VAF 108/727 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ORAI3 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 66/691 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2
- PCM1 | c.2165A>G p.K722R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PDGFB | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2
- PDILT | c.514A>T p.R172W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PDZD2 | c.5126G>T p.S1709I | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PGRMC2 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAA | c.1961C>A p.A654E | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POC1B | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- PRR19 | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PRSS53 | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRUNE2 | c.5321A>C p.E1774A | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PSMD3 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN6 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 129/621 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.1843T>A p.W615R | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RHPN1 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RYR3 | c.10630G>A p.E3544K (on ENST00000389232; = p.E3545K on NM_001036.6) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SBF2 | c.3470T>C p.L1157S | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SDR42E2 | c.728T>A p.M243K | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- SEC63 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SHROOM3 | c.4346C>T p.P1449L | Missense Mutation (SNP) | VAF 209/621 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLIT2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 40/288 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPATC1 | c.1425C>A p.N475K | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPTBN5 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STC1 | c.497G>C p.S166T | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- STON1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.132); called by muse, mutect2
- SULT1E1 | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TMPO | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TOP1 | c.1562A>C p.Q521P | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TRIM33 | c.446_448del p.F149del | In Frame Del (DEL) | VAF 35/82 reads (43%) | called by mutect2, pindel, varscan2
- TTLL13P | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- VAMP7 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- VPS13B | c.3542G>A p.C1181Y | Missense Mutation (SNP) | VAF 80/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR45B | c.965_993del p.F322Cfs*11 | Frame Shift Del (DEL) | VAF 127/230 reads (55%) | called by mutect2, pindel, varscan2
- WWC2 | c.3132G>T p.R1044S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YIF1B | c.890T>A p.V297E (on ENST00000339413 / NM_001039673.3; = p.V282E on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ZAP70 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 70/431 reads (16%) | called by muse, mutect2, varscan2
- ZBTB38 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABAT | c.1348C>A p.R450= | Silent (SNP) | VAF 97/572 reads (17%) | called by muse, mutect2
- C2CD2L | c.663C>G p.P221= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.3939T>A p.S1313= (on ENST00000236925 / NM_001297707.2; = p.S1302= on NM_203459.3) | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- CCDC88A | c.1278A>G p.S426= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1311922974; called by muse, mutect2, varscan2
- CYP2R1 | c.1263T>C p.H421= | Silent (SNP) | VAF 24/175 reads (14%) | called by muse, varscan2
- DENND4C | c.795C>T p.A265= | Silent (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- DNAH11 | c.3465C>T p.S1155= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs755144481, COSV100180464; called by muse, mutect2, varscan2
- EEFSEC | c.735C>A p.I245= | Silent (SNP) | VAF 69/273 reads (25%) | called by muse, mutect2, varscan2
- EXD1 | c.1182T>C p.H394= | Silent (SNP) | VAF 80/125 reads (64%) | called by muse, mutect2, varscan2
- FER1L6 | c.2019A>T p.A673= | Silent (SNP) | VAF 25/160 reads (16%) | called by muse, varscan2
- GIMAP8 | c.1632T>A p.A544= | Silent (SNP) | VAF 31/275 reads (11%) | called by muse, mutect2, varscan2
- GPR182 | c.726C>G p.A242= | Silent (SNP) | VAF 85/405 reads (21%) | called by muse, mutect2, varscan2
- IGSF1 | c.1866T>C p.F622= | Silent (SNP) | VAF 60/340 reads (18%) | called by muse, mutect2, varscan2
- IPO8 | c.519A>T p.I173= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- KALRN | c.4725T>C p.I1575= | Silent (SNP) | VAF 41/298 reads (14%) | called by muse, mutect2, varscan2
- KRT15 | c.75T>C p.A25= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- LRRK2 | c.6225G>A p.E2075= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- MAP3K11 | c.1110C>G p.A370= | Silent (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- NFRKB | c.3117C>G p.T1039= (on ENST00000446488 / NM_001143835.2; = p.T1064= on NM_006165.3) | Silent (SNP) | VAF 97/314 reads (31%) | called by muse, mutect2, varscan2
- PCDHB4 | c.141G>T p.L47= | Silent (SNP) | VAF 73/133 reads (55%) | called by muse, mutect2, varscan2
- PKN1 | c.2629C>T p.L877= | Silent (SNP) | VAF 34/519 reads (7%) | catalogued as rs1126938; called by muse, mutect2
- PLXNB1 | c.138C>T p.T46= | Silent (SNP) | VAF 197/426 reads (46%) | catalogued as rs1244187902, COSV56489975; called by muse, mutect2, varscan2
- REG3G | c.381G>C p.V127= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- RPN1 | c.762A>G p.G254= | Silent (SNP) | VAF 62/432 reads (14%) | called by muse, mutect2, varscan2
- TAS1R3 | c.81G>A p.Q27= | Silent (SNP) | VAF 129/175 reads (74%) | catalogued as COSV59562429; called by muse, mutect2, varscan2
- TRAF2 | c.559T>C p.L187= | Silent (SNP) | VAF 64/361 reads (18%) | called by muse, mutect2, varscan2
- ZC3H11A | c.516G>A p.E172= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as COSV100142664; called by muse, mutect2, varscan2
- ZNF688 | c.627G>A p.R209= | Silent (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- ADAD2 | c.607+25_607+27delinsAC | Intron (DEL) | VAF 24/282 reads (9%) | called by mutect2*, pindel
- AL353804.7 | chrX:73851989 T>C | 3'Flank (SNP) | VAF 24/102 reads (24%) | catalogued as rs1290721016; called by muse, mutect2, varscan2
- ALS2CL | c.2255+9_2255+23del | Intron (DEL) | VAF 20/96 reads (21%) | called by mutect2, varscan2
- ASH1L | chr1:155562779 C>T | 5'Flank (SNP) | VAF 18/142 reads (13%) | catalogued as rs1207414779; called by muse, mutect2, varscan2
- BPHL | c.107+492C>A | Intron (SNP) | VAF 27/219 reads (12%) | called by muse, mutect2, varscan2
- C2orf80 | c.573+2468G>A | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as rs1434801597; called by muse, mutect2, varscan2
- CC2D1A | c.-75G>C | 5'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- CEP170 | c.*285C>G | 3'UTR (SNP) | VAF 29/181 reads (16%) | called by muse, mutect2, varscan2
- CHN1 | c.712+2703C>T | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2, varscan2
- CLU | c.*1287C>T | 3'UTR (SNP) | VAF 35/87 reads (40%) | catalogued as rs895379599; called by muse, mutect2, varscan2
- CTCFL | chr20:57496323 C>A | 3'Flank (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- DENND6B | c.1139-23_1139-12delinsG | Intron (DEL) | VAF 31/72 reads (43%) | called by pindel, varscan2*
- DPP10 | c.61-244487T>A | Intron (SNP) | VAF 30/103 reads (29%) | catalogued as COSV101272197; called by muse, mutect2, varscan2
- DST | c.4297-1799C>G | Intron (SNP) | VAF 41/435 reads (9%) | called by muse, mutect2
- FBF1 | c.2773-14G>A | Intron (SNP) | VAF 100/152 reads (66%) | catalogued as rs758243151, COSV100044673; called by muse, mutect2, varscan2
- FMO6P | n.898C>A | RNA (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- GABRE | c.784+244A>G | Intron (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- GAS8 | chr16:90020057 C>A | 5'Flank (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- GVINP1 | n.2981A>T | RNA (SNP) | VAF 86/149 reads (58%) | called by muse, mutect2, varscan2
- KCNC3 | chr19:50334018 G>A | 5'Flank (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- LINC02692 | n.197_218del | RNA (DEL) | VAF 36/236 reads (15%) | called by mutect2, pindel, varscan2
- LRRC71 | c.594-15C>G | Intron (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- MC2R | c.-28A>G | 5'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- MGAM | c.4618+10744C>G | Intron (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- NDUFB9 | c.295-76_295-44del | Intron (DEL) | VAF 44/296 reads (15%) | called by mutect2, varscan2
- NPIPP1 | n.973A>G | RNA (SNP) | VAF 119/327 reads (36%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157831 del T | 5'Flank (DEL) | VAF 66/156 reads (42%) | called by mutect2, pindel, varscan2
- RNASET2 | c.446+239G>T | Intron (SNP) | VAF 29/564 reads (5%) | called by muse, mutect2
- RPL34-DT | n.303C>T | RNA (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- RPL7A | c.125-152A>C | Intron (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- SETD2 | chr3:47012634 A>G | 3'Flank (SNP) | VAF 63/242 reads (26%) | called by muse, varscan2
- SH3PXD2B | c.*4659del | 3'UTR (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- TDGF1 | c.*13_*57del | 3'UTR (DEL) | VAF 52/336 reads (15%) | called by mutect2, pindel
- TRPM3 | c.1278+58T>A | Intron (SNP) | VAF 58/295 reads (20%) | called by muse, mutect2, varscan2
- VAPB | c.*5849G>C | 3'UTR (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- WDFY4 | c.5982+672T>A | Intron (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- ZNF208 | c.*533C>G | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- ZNF529 | chr19:36574834 C>G | 5'Flank (SNP) | VAF 55/140 reads (39%) | catalogued as rs746191938; called by muse, mutect2, varscan2
- ZNF812P | n.1120T>G | RNA (SNP) | VAF 32/337 reads (9%) | called by muse, mutect2
